Somatic mutation profile of tumor specimen TCGA-BA-4078-01A (aliquot TCGA-BA-4078-01A-01D-1434-08) from TCGA case TCGA-BA-4078, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; Tumor grade: G2; Age at diagnosis: 83.4 years (30,480 days).
Specimen TCGA-BA-4078-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f1a11be0-acb0-4ce6-8aab-944ca92b2631.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BA-4078-10A (Blood Derived Normal), aliquot TCGA-BA-4078-10A-01D-1434-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/09ae5855-81e2-43dc-8128-d6b0889601f2

The open-access MAF lists 502 somatic variants for this specimen: 367 protein-altering or splice-affecting, 122 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 310, Silent 122, Nonsense Mutation 29, Splice Site 12, Frame Shift Del 9, Intron 5, Frame Shift Ins 5, RNA 4, 3'UTR 2, In Frame Del 1, 5'Flank 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CD247 | c.208C>T p.Q70* | Nonsense Mutation (SNP) | VAF 70/202 reads (35%) | catalogued as rs74315290, CM061679, COSV100758431; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.673-2A>G p.X225_splice | Splice Site (SNP) | VAF 58/67 reads (87%) | hotspot (GDC flag); catalogued as rs1555525585, CS109519, COSV52669186, COSV52682653, COSV52687702; ClinVar: likely pathogenic / pathogenic / not provided; called by muse, mutect2, varscan2
- A1CF | c.1212C>A p.Y404* (on ENST00000373993 / NM_138932.2; = p.Y396* on NM_014576.4) | Nonsense Mutation (SNP) | VAF 105/138 reads (76%) | catalogued as COSV99257018; called by muse, mutect2, varscan2
- ABCA9 | c.328G>C p.D110H | Missense Mutation (SNP) | VAF 66/207 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100383304; called by muse, mutect2, varscan2
- ABCC9 | c.4183G>T p.D1395Y | Missense Mutation (SNP) | VAF 61/184 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99686347; called by muse, mutect2, varscan2
- ABCC9 | c.2075A>G p.D692G | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.044); catalogued as COSV99686348; called by muse, mutect2, varscan2
- ACAN | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); catalogued as COSV100718697; called by muse, mutect2, varscan2
- ACTR5 | c.1433+1G>A p.X478_splice | Splice Site (SNP) | VAF 398/556 reads (72%) | catalogued as COSV99710127; called by muse, mutect2, varscan2
- ADAL | c.166G>A p.D56N | Missense Mutation (SNP) | VAF 100/218 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as COSV101052569; called by muse, mutect2, varscan2
- ADAM2 | c.1749C>A p.D583E | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as COSV99696827; called by muse, mutect2, varscan2
- ADAM29 | c.67G>T p.E23* | Nonsense Mutation (SNP) | VAF 67/90 reads (74%) | catalogued as COSV100822135; called by muse, mutect2, varscan2
- ADAMTS12 | c.2684C>A p.S895* | Nonsense Mutation (SNP) | VAF 49/179 reads (27%) | catalogued as COSV100711384, COSV61255573; called by muse, mutect2, varscan2
- ADGRG4 | c.6968A>T p.Y2323F | Missense Mutation (SNP) | VAF 169/210 reads (80%) | SIFT deleterious (0.03); PolyPhen benign (0.124); catalogued as COSV99796085; called by muse, mutect2, varscan2
- ADGRG7 | c.296G>T p.G99V | Missense Mutation (SNP) | VAF 101/224 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as COSV99841333, COSV99841708; called by muse, mutect2, varscan2
- ADGRG7 | c.1570C>A p.P524T | Missense Mutation (SNP) | VAF 310/733 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as COSV99841334; called by muse, mutect2, varscan2
- ADGRL2 | c.767A>G p.Y256C | Missense Mutation (SNP) | VAF 65/159 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99590281; called by muse, mutect2, varscan2
- ADGRL2 | c.3035C>A p.T1012K (on ENST00000370717 / NM_001366005.1; = p.T999K on NM_012302.4) | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV99590287; called by muse, mutect2, varscan2
- ADGRV1 | c.2406G>T p.R802S | Missense Mutation (SNP) | VAF 98/125 reads (78%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.724); catalogued as COSV101316216; called by muse, mutect2, varscan2
- AFF3 | c.118C>A p.Q40K | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV100419597, COSV57855617; called by muse, mutect2, varscan2
- AGAP3 | c.1672G>A p.D558N (on ENST00000622464; = p.D594N on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV101257291; called by muse, mutect2, varscan2
- AKR1D1 | c.154A>G p.I52V | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.073); catalogued as COSV99653194; called by muse, mutect2, varscan2
- AMIGO3 | c.1280A>C p.Q427P | Missense Mutation (SNP) | VAF 81/111 reads (73%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as COSV100246662; called by muse, mutect2, varscan2
- AMPD1 | c.151C>A p.R51S | Missense Mutation (SNP) | VAF 75/229 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs369335745, COSV100815133, COSV62416441; called by muse, mutect2, varscan2
- ANGPT4 | c.389C>G p.P130R | Missense Mutation (SNP) | VAF 69/205 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.289); catalogued as COSV101124815; called by muse, mutect2, varscan2
- APOB | c.2939C>T p.A980V | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.998); catalogued as COSV99266688; called by muse, mutect2, varscan2
- ARHGEF4 | c.974A>T p.Q325L | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.322); catalogued as COSV100388423; called by muse, mutect2, varscan2
- ARID3B | c.574G>A p.D192N | Missense Mutation (SNP) | VAF 39/123 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.612); catalogued as COSV100654681; called by muse, mutect2, varscan2
- ARID4B | c.2765A>C p.K922T | Missense Mutation (SNP) | VAF 201/236 reads (85%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as COSV99935939; called by muse, mutect2, varscan2
- ASB10 | c.841C>T p.L281F (on ENST00000420175 / NM_001142459.2; = p.L266F on NM_080871.4) | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99318777; called by muse, mutect2, varscan2
- ASIC5 | c.1327G>T p.A443S | Missense Mutation (SNP) | VAF 55/82 reads (67%) | SIFT tolerated (0.47); PolyPhen benign (0.272); catalogued as COSV101611158; called by muse, mutect2, varscan2
- ASIC5 | c.771C>G p.I257M | Missense Mutation (SNP) | VAF 44/64 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV101611159; called by muse, mutect2, varscan2
- ATG2A | c.4412A>G p.Q1471R | Missense Mutation (SNP) | VAF 78/192 reads (41%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.549); catalogued as rs762113071, COSV101034597; called by muse, mutect2, varscan2
- ATG2B | c.4042A>T p.T1348S | Missense Mutation (SNP) | VAF 123/159 reads (77%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.996); catalogued as COSV99952144; called by muse, mutect2, varscan2
- ATP10A | c.479G>T p.W160L | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV100791390; called by muse, varscan2
- ATP10B | c.80C>T p.T27I | Missense Mutation (SNP) | VAF 69/101 reads (68%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1278789209, COSV100469586; called by muse, mutect2, varscan2
- ATP6V1B1 | c.793C>G p.R265G | Missense Mutation (SNP) | VAF 37/129 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99314343; called by muse, mutect2, varscan2
- ATP8A2 | c.1226T>A p.M409K | Missense Mutation (SNP) | VAF 72/94 reads (77%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.964); catalogued as COSV99683039; called by muse, mutect2, varscan2
- ATP8B4 | c.209C>A p.P70Q | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99466595; called by muse, mutect2, varscan2
- ATRNL1 | c.2251G>T p.G751* | Nonsense Mutation (SNP) | VAF 43/59 reads (73%) | catalogued as COSV100746526; called by muse, mutect2, varscan2
- ATXN7L2 | c.1289G>A p.R430H | Missense Mutation (SNP) | VAF 65/146 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100149833; called by muse, mutect2, varscan2
- AVIL | c.1880A>C p.Q627P | Missense Mutation (SNP) | VAF 144/368 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.154); catalogued as COSV99142494; called by muse, mutect2, varscan2
- BCL2A1 | c.358T>C p.Y120H | Missense Mutation (SNP) | VAF 135/317 reads (43%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV51213765; called by muse, mutect2, varscan2
- BLK | c.1069A>G p.I357V | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.874); catalogued as COSV99377414; called by muse, mutect2, varscan2
- BRI3 | c.332C>T p.A111V | Missense Mutation (SNP) | VAF 102/227 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs867982825, COSV99134464; called by muse, mutect2, varscan2
- BSX | c.313G>T p.G105W | Missense Mutation (SNP) | VAF 35/51 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV100545275, COSV58005870; called by muse, mutect2, varscan2
- C16orf70 | c.613C>T p.R205* | Nonsense Mutation (SNP) | VAF 269/354 reads (76%) | catalogued as rs760589547, COSV54626428; called by muse, mutect2, varscan2
- C1QTNF6 | c.5A>G p.Q2R | Missense Mutation (SNP) | VAF 137/158 reads (87%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV100547983; called by muse, mutect2, varscan2
- C2orf88 | c.230G>A p.W77* | Nonsense Mutation (SNP) | VAF 141/373 reads (38%) | catalogued as COSV100502879; called by muse, mutect2, varscan2
- C5orf34 | c.1081G>T p.V361F | Missense Mutation (SNP) | VAF 76/286 reads (27%) | SIFT tolerated (0.51); PolyPhen benign (0.238); catalogued as COSV100175528; called by muse, mutect2, varscan2
- C7orf26 | c.1057G>T p.A353S | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1306981317, COSV100732960; called by muse, mutect2, varscan2
- C8B | c.181A>T p.M61L | Missense Mutation (SNP) | VAF 60/145 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV100980826; called by muse, mutect2, varscan2
- CACNA2D1 | c.729G>T p.W243C | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.623); catalogued as COSV100666950; called by muse, mutect2, varscan2
- CAPN10 | c.795G>T p.W265C | Missense Mutation (SNP) | VAF 93/215 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99550392; called by muse, mutect2, varscan2
- CAPNS2 | c.611T>C p.M204T | Missense Mutation (SNP) | VAF 216/291 reads (74%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); catalogued as rs567078741, COSV100045065; called by muse, mutect2, varscan2
- CATSPERD | c.145C>A p.P49T | Missense Mutation (SNP) | VAF 66/156 reads (42%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as COSV101062685; called by muse, mutect2, varscan2
- CCDC50 | c.307C>T p.R103C | Missense Mutation (SNP) | VAF 34/223 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs755289135, COSV101165331; called by muse, mutect2, varscan2
- CCDC57 | c.65G>A p.R22K | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.978); catalogued as rs749455808, COSV101051986; called by muse, mutect2, varscan2
- CCZ1B | c.334G>T p.E112* | Nonsense Mutation (SNP) | VAF 11/58 reads (19%) | catalogued as COSV100367933; called by muse, mutect2, varscan2
- CD22 | c.878C>T p.T293M | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.179); catalogued as rs757254943, COSV99323488; called by muse, mutect2, varscan2
- CDH10 | c.1346G>T p.R449L | Missense Mutation (SNP) | VAF 33/149 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs749021068, COSV52603451; called by muse, mutect2, varscan2
- CDH7 | c.673C>A p.Q225K | Missense Mutation (SNP) | VAF 49/115 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.192); catalogued as COSV100542832; called by muse, mutect2, varscan2
- CELA3B | c.83G>T p.R28L | Missense Mutation (SNP) | VAF 50/79 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100448824; called by muse, mutect2, varscan2
- CENPF | c.6434G>A p.R2145H | Missense Mutation (SNP) | VAF 97/111 reads (87%) | SIFT tolerated (0.07); PolyPhen benign (0.439); catalogued as rs1214262860, COSV100871811; called by muse, mutect2, varscan2
- CEP250 | c.6082G>A p.D2028N | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV100699060; called by muse, mutect2, varscan2
- CEP97 | c.1613C>G p.P538R | Missense Mutation (SNP) | VAF 94/477 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.4); catalogued as COSV100511968; called by muse, mutect2, varscan2
- CFAP221 | c.2423A>G p.K808R | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV99732852; called by muse, mutect2, varscan2
- CFAP61 | c.1739G>T p.R580L | Missense Mutation (SNP) | VAF 126/324 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55620136, COSV99845764; called by muse, mutect2, varscan2
- CHRND | c.698G>T p.R233L | Missense Mutation (SNP) | VAF 62/184 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.091); catalogued as rs146416320, COSV51317337, COSV99285993; called by muse, mutect2, varscan2
- CHSY3 | c.1544G>T p.R515L | Missense Mutation (SNP) | VAF 40/53 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100519385, COSV100519570; called by muse, mutect2, varscan2
- CLEC6A | c.616A>T p.K206* | Nonsense Mutation (SNP) | VAF 47/127 reads (37%) | catalogued as COSV101165675, COSV65988195; called by muse, mutect2, varscan2
- CLSTN3 | c.1538A>T p.Q513L | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as COSV99867351; called by muse, mutect2, varscan2
- CNBD1 | c.1078G>T p.G360C | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as COSV101582276; called by muse, mutect2, varscan2
- CNNM1 | c.1720G>C p.D574H | Missense Mutation (SNP) | VAF 155/220 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV100763929; called by muse, mutect2, varscan2
- CNTNAP2 | c.1325T>A p.M442K | Missense Mutation (SNP) | VAF 54/130 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100668562; called by muse, mutect2, varscan2
- COL22A1 | c.3680C>A p.P1227H | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV100279431; called by muse, mutect2, varscan2
- COL22A1 | c.3643C>T p.P1215S | Missense Mutation (SNP) | VAF 164/385 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV100279432; called by muse, varscan2
- COL27A1 | c.4025C>A p.P1342H | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV100621143; called by muse, mutect2, varscan2
- COL4A4 | c.244C>T p.P82S | Missense Mutation (SNP) | VAF 67/147 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.056); catalogued as COSV100307330; called by muse, mutect2, varscan2
- COL6A3 | c.3371C>G p.A1124G | Missense Mutation (SNP) | VAF 47/120 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.422); catalogued as COSV99799860; called by muse, mutect2, varscan2
- COL6A5 | c.7336G>T p.G2446C (on ENST00000312481; = p.G2442C on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1011075637, COSV99593893; called by muse, mutect2, varscan2
- CPED1 | c.232G>A p.A78T | Missense Mutation (SNP) | VAF 63/170 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV100121144; called by muse, mutect2, varscan2
- CREB5 | c.110G>A p.R37K (on ENST00000357727 / NM_182898.4; = p.R30K on NM_004904.3) | Missense Mutation (SNP) | VAF 87/233 reads (37%) | SIFT tolerated (1); PolyPhen possibly damaging (0.899); catalogued as COSV100745064; called by muse, mutect2, varscan2
- CTDSP1 | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 57/138 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV99812033; called by muse, mutect2, varscan2
- CTNNA2 | c.910G>T p.E304* | Nonsense Mutation (SNP) | VAF 80/218 reads (37%) | catalogued as COSV100785273; called by muse, mutect2, varscan2
- CTNNA3 | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 49/74 reads (66%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.989); catalogued as rs777718965, COSV100373681; called by muse, mutect2, varscan2
- CTNND1 | c.1388C>A p.A463D | Missense Mutation (SNP) | VAF 175/504 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.322); catalogued as rs755094282, COSV100650191; called by muse, mutect2, varscan2
- CTNND2 | c.1428C>A p.H476Q | Missense Mutation (SNP) | VAF 46/154 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.119); catalogued as COSV100478984, COSV58922136; called by muse, mutect2, varscan2
- CUBN | c.3834T>G p.C1278W | Missense Mutation (SNP) | VAF 70/91 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100913104; called by muse, mutect2, varscan2
- CUBN | c.1709C>T p.S570F | Missense Mutation (SNP) | VAF 113/154 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100913105; called by muse, mutect2, varscan2
- CUX1 | c.1084A>T p.K362* (on ENST00000292535 / NM_181552.4; = p.K373* on NM_001913.5) | Nonsense Mutation (SNP) | VAF 26/55 reads (47%) | catalogued as COSV99472330; called by muse, mutect2
- CYP2B6 | c.857A>T p.Q286L | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.14); catalogued as COSV100137648; called by muse, mutect2, varscan2
- CYP4A11 | c.40G>T p.D14Y | Missense Mutation (SNP) | VAF 73/213 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.285); catalogued as rs1156955746, COSV100152510, COSV60225151; called by muse, mutect2, varscan2
- CYP4A22 | c.636-2A>C p.X212_splice | Splice Site (SNP) | VAF 55/131 reads (42%) | catalogued as COSV99595172; called by muse, mutect2, varscan2
- DACH2 | c.1194T>A p.S398R | Missense Mutation (SNP) | VAF 22/26 reads (85%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV100913602; called by muse, mutect2, varscan2
- DCC | c.707T>A p.L236Q | Missense Mutation (SNP) | VAF 41/149 reads (28%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV100499887, COSV100501623; called by muse, mutect2, varscan2
- DCC | c.3742G>C p.V1248L | Missense Mutation (SNP) | VAF 86/200 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.896); catalogued as COSV101473359, COSV71429727; called by muse, mutect2, varscan2
- DCSTAMP | c.842C>G p.P281R | Missense Mutation (SNP) | VAF 112/244 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99886752, COSV99887135; called by muse, mutect2, varscan2
- DDX42 | c.1988G>T p.R663L | Missense Mutation (SNP) | VAF 53/170 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV100834985; called by muse, mutect2, varscan2
- DDX56 | c.1286G>T p.R429L | Missense Mutation (SNP) | VAF 57/132 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99346159; called by muse, mutect2, varscan2
- DEPDC4 | c.80A>G p.N27S | Missense Mutation (SNP) | VAF 98/226 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100147397; called by muse, mutect2, varscan2
- DHRS7C | c.278C>A p.T93N (on ENST00000330255 / NM_001220493.2; = p.T92N on NM_001105571.3) | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.878); catalogued as COSV100364819, COSV57650808; called by muse, mutect2, varscan2
- DICER1 | c.646C>T p.P216S | Missense Mutation (SNP) | VAF 60/82 reads (73%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV100602303; called by muse, mutect2, varscan2
- DLGAP4 | c.814G>A p.A272T | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as rs529565051, COSV59414419; called by muse, mutect2, varscan2
- DMD | c.7028G>C p.W2343S | Missense Mutation (SNP) | VAF 24/32 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100628378; called by muse, varscan2
- DNAH11 | c.5938G>T p.G1980W | Missense Mutation (SNP) | VAF 121/301 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100179871; called by muse, mutect2, varscan2
- DNAH5 | c.10910T>C p.L3637P | Missense Mutation (SNP) | VAF 72/231 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99451833; called by muse, mutect2, varscan2
- DNAH5 | c.5335G>C p.V1779L | Missense Mutation (SNP) | VAF 53/258 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); catalogued as COSV99451834; called by muse, mutect2, varscan2
- DNAH5 | c.2347G>T p.E783* | Nonsense Mutation (SNP) | VAF 104/331 reads (31%) | catalogued as COSV99451836; called by muse, mutect2, varscan2
- DNAH7 | c.10654A>T p.I3552F | Missense Mutation (SNP) | VAF 74/173 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.694); catalogued as COSV100416302; called by muse, mutect2, varscan2
- DNAH9 | c.5391+2T>C p.X1797_splice | Splice Site (SNP) | VAF 31/91 reads (34%) | catalogued as COSV99306894; called by muse, mutect2, varscan2
- DNAJC22 | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 35/118 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV101222577; called by muse, mutect2, varscan2
- DNHD1 | c.13631G>A p.G4544D | Missense Mutation (SNP) | VAF 16/20 reads (80%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99600569; called by muse, mutect2, varscan2
- DPY19L3 | c.2125G>T p.V709F | Missense Mutation (SNP) | VAF 119/287 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100639235; called by muse, mutect2, varscan2
- DPYSL2 | c.1066A>T p.N356Y | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100234012; called by muse, mutect2, varscan2
- EFR3A | c.791A>G p.H264R | Missense Mutation (SNP) | VAF 46/126 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.734); catalogued as rs1021534572, COSV54460018; called by muse, mutect2, varscan2
- ELAVL4 | c.412G>A p.G138S | Missense Mutation (SNP) | VAF 110/256 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.888); catalogued as rs199932597, COSV100836492, COSV63915579; called by muse, mutect2, varscan2
- ENPP2 | c.1207+1G>T p.X403_splice (on ENST00000075322 / NM_001040092.3; = p.X455_splice on NM_006209.5) | Splice Site (SNP) | VAF 30/72 reads (42%) | catalogued as COSV99308845; called by muse, mutect2, varscan2
- EOMES | c.62C>A p.P21Q | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.308); catalogued as COSV55412653, COSV55415394; called by muse, mutect2, varscan2
- EPS15L1 | c.874G>T p.G292C | Missense Mutation (SNP) | VAF 58/121 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99933388; called by muse, mutect2, varscan2
- ERBB4 | c.2840T>C p.I947T | Missense Mutation (SNP) | VAF 77/194 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs370965857; called by muse, mutect2, varscan2
- ERICH3 | c.4039G>T p.G1347C | Missense Mutation (SNP) | VAF 74/179 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); catalogued as COSV100445035; called by muse, varscan2
- ERICH6 | c.853G>T p.V285L | Missense Mutation (SNP) | VAF 101/245 reads (41%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV99901819; called by muse, mutect2, varscan2
- ERMAP | c.1216A>G p.T406A | Missense Mutation (SNP) | VAF 64/184 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV100072321; called by muse, mutect2, varscan2
- EXOC2 | c.620G>C p.G207A | Missense Mutation (SNP) | VAF 68/133 reads (51%) | SIFT tolerated (0.44); PolyPhen benign (0.292); catalogued as COSV100033921; called by muse, mutect2, varscan2
- F13B | c.355G>T p.A119S | Missense Mutation (SNP) | VAF 47/66 reads (71%) | SIFT tolerated (0.76); PolyPhen benign (0.031); catalogued as rs778659939, COSV100803351, COSV66372407; called by muse, mutect2, varscan2
- FAM135B | c.1253C>A p.A418E | Missense Mutation (SNP) | VAF 98/226 reads (43%) | SIFT tolerated (0.96); PolyPhen benign (0.103); catalogued as COSV99419121, COSV99425733; called by muse, mutect2, varscan2
- FAM184A | c.1394A>G p.Q465R | Missense Mutation (SNP) | VAF 57/142 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as COSV100138078; called by muse, mutect2, varscan2
- FAM47C | c.1015G>T p.V339L | Missense Mutation (SNP) | VAF 102/127 reads (80%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.9); catalogued as COSV100792813; called by muse, mutect2, varscan2
- FAR1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 45/67 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); catalogued as COSV100701611; called by muse, mutect2, varscan2
- FASN | c.5374C>T p.H1792Y | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750492722, COSV100148081; called by muse, mutect2, varscan2
- FAT1 | c.517G>C p.A173P | Missense Mutation (SNP) | VAF 152/191 reads (80%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV101499462, COSV71673513; called by muse, mutect2, varscan2
- FBXL7 | c.1040A>T p.K347M | Missense Mutation (SNP) | VAF 27/41 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV100310285; called by muse, mutect2, varscan2
- FCHO1 | c.1100G>T p.R367L | Missense Mutation (SNP) | VAF 66/142 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.179); catalogued as rs751850968, COSV99406271; called by muse, mutect2, varscan2
- FGA | c.1486G>T p.D496Y | Missense Mutation (SNP) | VAF 94/129 reads (73%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV100120550; called by muse, mutect2, varscan2
- FGD4 | c.403A>G p.T135A | Missense Mutation (SNP) | VAF 46/153 reads (30%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as COSV99847379; called by muse, mutect2, varscan2
- FILIP1L | c.3355C>T p.P1119S (on ENST00000354552 / NM_182909.3; = p.P879S on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 114/510 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs1317584722, COSV100497145; called by muse, varscan2
- FLG | c.6596C>A p.S2199* | Nonsense Mutation (SNP) | VAF 310/747 reads (41%) | catalogued as COSV100911828, COSV64242177; called by muse, mutect2, varscan2
- FLNC | c.4538A>G p.Y1513C | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.457); catalogued as COSV100368421; called by muse, mutect2, varscan2
- FOLH1 | c.931G>T p.G311C | Missense Mutation (SNP) | VAF 69/172 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99923560; called by muse, mutect2, varscan2
- FOLH1 | c.688G>C p.D230H | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99923561; called by muse, mutect2, varscan2
- FOXP1 | c.139G>T p.G47W | Missense Mutation (SNP) | VAF 92/138 reads (67%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV100562024; called by muse, mutect2, varscan2
- GABRA3 | c.224T>C p.L75P | Missense Mutation (SNP) | VAF 76/91 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1330522002, COSV100943077; called by muse, mutect2, varscan2
- GABRA4 | c.1384G>C p.G462R | Missense Mutation (SNP) | VAF 70/89 reads (79%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.137); catalogued as COSV99974324; called by muse, mutect2, varscan2
- GAD2 | c.593C>A p.S198* | Nonsense Mutation (SNP) | VAF 44/58 reads (76%) | catalogued as COSV99393648; called by muse, mutect2, varscan2
- GALC | c.1622G>A p.W541* | Nonsense Mutation (SNP) | VAF 60/85 reads (71%) | catalogued as CM1512167, COSV99730116; called by muse, mutect2, varscan2
- GFRAL | c.533T>A p.I178K | Missense Mutation (SNP) | VAF 180/422 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as COSV100475545; called by muse, mutect2, varscan2
- GJA10 | c.421C>T p.Q141* | Nonsense Mutation (SNP) | VAF 51/125 reads (41%) | catalogued as COSV101005408; called by muse, mutect2, varscan2
- GLG1 | c.1571+1G>A p.X524_splice | Splice Site (SNP) | VAF 74/101 reads (73%) | catalogued as COSV99216061; called by muse, mutect2, varscan2
- GNL2 | c.1414del p.Q472Sfs*140 | Frame Shift Del (DEL) | VAF 15/43 reads (35%) | catalogued as rs758338395, COSV66081403; called by mutect2, pindel, varscan2
- GPATCH8 | c.3160A>T p.R1054* | Nonsense Mutation (SNP) | VAF 58/131 reads (44%) | catalogued as COSV100132745; called by muse, mutect2, varscan2
- GRIA3 | c.2291A>T p.Y764F | Missense Mutation (SNP) | VAF 100/124 reads (81%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.987); catalogued as COSV99990966; called by muse, mutect2, varscan2
- GSTA3 | c.518G>A p.S173N | Missense Mutation (SNP) | VAF 83/218 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV99274604; called by muse, mutect2, varscan2
- GTPBP4 | c.31G>T p.V11L | Missense Mutation (SNP) | VAF 23/29 reads (79%) | SIFT tolerated (0.08); PolyPhen benign (0.415); catalogued as COSV100672831; called by muse, mutect2, varscan2
- H1-6 | c.490G>C p.V164L | Missense Mutation (SNP) | VAF 176/427 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV100619601; called by muse, mutect2, varscan2
- HOXC13 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 166/406 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV99673522; called by muse, mutect2, varscan2
- HOXD8 | c.346C>A p.P116T | Missense Mutation (SNP) | VAF 91/204 reads (45%) | SIFT tolerated (0.38); PolyPhen benign (0.012); catalogued as COSV100497130; called by muse, mutect2, varscan2
- IARS1 | c.262C>A p.H88N | Missense Mutation (SNP) | VAF 69/147 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100986843, COSV65114802; called by muse, mutect2, varscan2
- IGKV1D-17 | c.350C>A p.P117H | Missense Mutation (SNP) | VAF 67/201 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746721782; called by muse, mutect2, varscan2
- INSYN2A | c.252C>A p.Y84* | Nonsense Mutation (SNP) | VAF 72/95 reads (76%) | catalogued as COSV99731214; called by muse, mutect2, varscan2
- KCNJ1 | c.220G>C p.D74H | Missense Mutation (SNP) | VAF 107/162 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as CM970806, COSV100131400; called by muse, mutect2, varscan2
- KCNT2 | c.2366G>C p.R789T | Missense Mutation (SNP) | VAF 33/40 reads (83%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as COSV54061829, COSV99655319; called by muse, mutect2, varscan2
- KCNV1 | c.556C>A p.Q186K | Missense Mutation (SNP) | VAF 64/167 reads (38%) | SIFT tolerated (0.73); PolyPhen benign (0.033); catalogued as COSV99819249; called by muse, mutect2, varscan2
- KDM4B | c.2023G>T p.A675S | Missense Mutation (SNP) | VAF 111/274 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.572); catalogued as rs762681895, COSV50208695, COSV99346873; called by muse, mutect2, varscan2
- KIAA1109 | c.9219A>G p.I3073M | Missense Mutation (SNP) | VAF 68/92 reads (74%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV99167662; called by muse, mutect2, varscan2
- KIF16B | c.838G>T p.V280L | Missense Mutation (SNP) | VAF 84/473 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100734669; called by muse, mutect2, varscan2
- KRT73 | c.272T>C p.L91S | Missense Mutation (SNP) | VAF 125/297 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as rs745838280, COSV99988679; called by muse, mutect2, varscan2
- KRTAP10-8 | c.676C>T p.P226S | Missense Mutation (SNP) | VAF 67/158 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1437432508, COSV58167498; called by muse, mutect2, varscan2
- LAMA2 | c.6691C>A p.R2231S | Missense Mutation (SNP) | VAF 52/102 reads (51%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.999); catalogued as COSV101370579; called by muse, mutect2, varscan2
- LIN28B | c.152G>A p.R51Q | Missense Mutation (SNP) | VAF 109/277 reads (39%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.886); catalogued as COSV100558655; called by muse, mutect2, varscan2
- LINGO1 | c.1214A>T p.K405M | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.063); catalogued as COSV100796454; called by muse, mutect2, varscan2
- LRIG2 | c.1525G>T p.A509S | Missense Mutation (SNP) | VAF 70/190 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.639); catalogued as COSV100743535; called by muse, mutect2, varscan2
- LRP1B | c.6124C>T p.P2042S | Missense Mutation (SNP) | VAF 51/175 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV101258213; called by muse, mutect2, varscan2
- MAGEA6 | c.536C>G p.A179G | Missense Mutation (SNP) | VAF 105/125 reads (84%) | SIFT deleterious (0.03); PolyPhen benign (0.18); catalogued as COSV100262906; called by muse, mutect2, varscan2
- MAP6 | c.1086C>G p.S362R | Missense Mutation (SNP) | VAF 62/88 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100496811; called by muse, mutect2, varscan2
- MAPRE2 | c.475G>C p.D159H | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100290774; called by muse, mutect2, varscan2
- MBD5 | c.2800C>G p.L934V | Missense Mutation (SNP) | VAF 124/366 reads (34%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.978); catalogued as COSV101290176; called by muse, mutect2, varscan2
- MMP10 | c.679C>T p.H227Y | Missense Mutation (SNP) | VAF 68/92 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99666655; called by muse, mutect2, varscan2
- MMP12 | c.448A>T p.S150C | Missense Mutation (SNP) | VAF 31/33 reads (94%) | SIFT deleterious (0); PolyPhen possibly damaging (0.45); catalogued as COSV100405013; called by muse, mutect2, varscan2
- MOB4 | c.431G>T p.S144I | Missense Mutation (SNP) | VAF 52/138 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99291139; called by muse, mutect2, varscan2
- MPDZ | c.1635G>A p.M545I | Missense Mutation (SNP) | VAF 12/15 reads (80%) | SIFT deleterious (0.01); PolyPhen benign (0.114); catalogued as rs757155024, COSV100061682, COSV100063661; called by muse, varscan2
- MSN | c.1570-1G>T p.X524_splice | Splice Site (SNP) | VAF 56/71 reads (79%) | catalogued as COSV100814259; called by muse, mutect2, varscan2
- MTNR1B | c.403G>C p.A135P | Missense Mutation (SNP) | VAF 60/74 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99925222; called by muse, mutect2, varscan2
- MTURN | c.106G>T p.D36Y | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.714); catalogued as COSV100188870, COSV61023480; called by muse, mutect2, varscan2
- MUC16 | c.36779G>T p.S12260I | Missense Mutation (SNP) | VAF 159/365 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.013); catalogued as COSV101200510; called by muse, mutect2, varscan2
- MUC16 | c.15443C>A p.P5148H | Missense Mutation (SNP) | VAF 137/312 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV101200511; called by muse, mutect2, varscan2
- MUC17 | c.2320A>T p.T774S | Missense Mutation (SNP) | VAF 231/554 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as rs1283491576, COSV100074267; called by muse, mutect2, varscan2
- MYCT1 | c.464C>G p.S155C | Missense Mutation (SNP) | VAF 84/217 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV100924080, COSV65891297; called by muse, mutect2, varscan2
- MYH10 | c.317A>G p.K106R | Missense Mutation (SNP) | VAF 96/213 reads (45%) | SIFT tolerated (0.57); PolyPhen benign (0.028); catalogued as COSV99345807; called by muse, mutect2, varscan2
- MYH13 | c.244C>A p.P82T | Missense Mutation (SNP) | VAF 99/279 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99354704; called by muse, mutect2, varscan2
- MYH6 | c.2098G>A p.V700M | Missense Mutation (SNP) | VAF 45/59 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs767142932, CM107533, COSV100676802; called by muse, mutect2, varscan2
- NDC80 | c.1727G>A p.R576Q | Missense Mutation (SNP) | VAF 92/234 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as rs774289304, COSV55247718; called by muse, mutect2, varscan2
- NGEF | c.79C>A p.P27T | Missense Mutation (SNP) | VAF 83/212 reads (39%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.007); catalogued as COSV99889940; called by muse, mutect2, varscan2
- NIPBL | c.8084C>T p.T2695M | Missense Mutation (SNP) | VAF 112/365 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.075); catalogued as rs766898203, COSV99241580; called by muse, mutect2, varscan2
- NKD1 | c.1049A>G p.K350R | Missense Mutation (SNP) | VAF 55/66 reads (83%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV99194083; called by muse, mutect2, varscan2
- NLRP10 | c.362A>G p.Y121C | Missense Mutation (SNP) | VAF 60/95 reads (63%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as COSV100149824; called by muse, mutect2, varscan2
- NLRP2 | c.1469G>C p.R490P | Missense Mutation (SNP) | VAF 53/147 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.723); catalogued as COSV54752314, COSV99672463; called by muse, mutect2, varscan2
- NLRP5 | c.1967C>A p.P656H | Missense Mutation (SNP) | VAF 80/200 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs200093654; called by muse, mutect2, varscan2
- NNMT | c.272T>A p.L91Q | Missense Mutation (SNP) | VAF 80/106 reads (75%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.499); catalogued as COSV100248903; called by muse, mutect2, varscan2
- NOL8 | c.1217C>G p.S406C | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.628); catalogued as COSV100694631; called by muse, mutect2, varscan2
- NOX1 | c.610T>C p.F204L | Missense Mutation (SNP) | VAF 226/276 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99471660; called by muse, mutect2, varscan2
- NPAP1 | c.356C>T p.P119L | Missense Mutation (SNP) | VAF 72/170 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.125); catalogued as COSV61512973; called by muse, mutect2, varscan2
- NPAS3 | c.1047G>C p.R349S (on ENST00000356141 / NM_001164749.2; = p.R317S on NM_022123.3) | Missense Mutation (SNP) | VAF 68/89 reads (76%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.449); catalogued as COSV100640413; called by muse, mutect2, varscan2
- NSUN3 | c.36G>T p.K12N | Missense Mutation (SNP) | VAF 32/160 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as COSV100113369; called by muse, mutect2
- NSUN3 | c.38T>A p.L13H | Missense Mutation (SNP) | VAF 32/156 reads (21%) | SIFT tolerated (0.55); PolyPhen benign (0.086); catalogued as COSV100113372; called by muse, mutect2
- NTSR2 | c.646G>T p.V216L | Missense Mutation (SNP) | VAF 104/263 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.165); catalogued as COSV100183966, COSV60991061; called by muse, mutect2, varscan2
- OCEL1 | c.57G>C p.Q19H | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as rs892240646, COSV99285773; called by muse, mutect2
- OR14I1 | c.566A>T p.E189V | Missense Mutation (SNP) | VAF 63/78 reads (81%) | SIFT deleterious (0.03); PolyPhen benign (0.099); catalogued as COSV100700510; called by muse, mutect2, varscan2
- OR2A25 | c.693G>C p.E231D | Missense Mutation (SNP) | VAF 94/238 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.32); catalogued as COSV101376403; called by muse, mutect2, varscan2
- OR2F2 | c.844A>T p.M282L | Missense Mutation (SNP) | VAF 92/210 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as COSV101283833; called by muse, mutect2, varscan2
- OR2G6 | c.305A>T p.Y102F | Missense Mutation (SNP) | VAF 138/159 reads (87%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.943); catalogued as COSV100598248; called by muse, varscan2
- OR2T12 | c.601T>A p.C201S | Missense Mutation (SNP) | VAF 114/151 reads (75%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100527691; called by muse, mutect2, varscan2
- OR2T34 | c.433G>C p.V145L | Missense Mutation (SNP) | VAF 77/107 reads (72%) | SIFT tolerated (0.31); PolyPhen benign (0.06); catalogued as rs755310345, COSV100170449, COSV60902062; called by muse, mutect2, varscan2
- OR4C3 | c.560G>T p.C187F | Missense Mutation (SNP) | VAF 61/159 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100168057; called by muse, varscan2
- OR4K1 | c.70C>T p.Q24* | Nonsense Mutation (SNP) | VAF 207/549 reads (38%) | catalogued as COSV99579151; called by muse, mutect2, varscan2
- OR51F1 | c.760G>T p.V254L | Missense Mutation (SNP) | VAF 50/74 reads (68%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV58578927; called by muse, mutect2, varscan2
- OR5A2 | c.851C>A p.P284H | Missense Mutation (SNP) | VAF 56/130 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100119800; called by muse, mutect2, varscan2
- OR5M10 | c.912G>A p.M304I | Missense Mutation (SNP) | VAF 169/410 reads (41%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV73242366; called by muse, mutect2, varscan2
- OR8B4 | c.47G>T p.G16V | Missense Mutation (SNP) | VAF 37/47 reads (79%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); catalogued as COSV100635842, COSV62069445; called by muse, mutect2, varscan2
- OR8K5 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 80/207 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.025); catalogued as rs992707736, COSV100537259, COSV57891286; called by muse, mutect2, varscan2
- OSBPL3 | c.2024C>T p.P675L | Missense Mutation (SNP) | VAF 126/280 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); catalogued as rs561433543, COSV100514343; called by muse, mutect2, varscan2
- OSBPL8 | c.561G>T p.W187C | Missense Mutation (SNP) | VAF 51/124 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99675334; called by muse, mutect2, varscan2
- PAGE4 | c.232G>T p.G78C | Missense Mutation (SNP) | VAF 65/78 reads (83%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as COSV99489849; called by muse, mutect2, varscan2
- PAIP2B | c.8G>T p.G3V | Missense Mutation (SNP) | VAF 82/175 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.864); catalogued as COSV54908527, COSV99731706; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.331G>T p.A111S (on ENST00000259318 / NM_001136562.3; = p.A342S on NM_007203.5) | Missense Mutation (SNP) | VAF 65/143 reads (45%) | SIFT tolerated (0.36); PolyPhen benign (0.046); catalogued as COSV99395483; called by muse, mutect2, varscan2
- PARP8 | c.2281A>G p.S761G | Missense Mutation (SNP) | VAF 32/40 reads (80%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV99892148; called by muse, mutect2, varscan2
- PAX1 | c.790G>T p.G264C | Missense Mutation (SNP) | VAF 50/99 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV101270344; called by muse, mutect2, varscan2
- PCDH15 | c.3875G>T p.R1292L | Missense Mutation (SNP) | VAF 79/94 reads (84%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.963); catalogued as COSV100224237, COSV57365083; called by muse, mutect2, varscan2
- PCDHGA3 | c.83C>G p.S28C | Missense Mutation (SNP) | VAF 203/277 reads (73%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.014); catalogued as COSV53895175, COSV53932691, COSV99542394; called by muse, mutect2, varscan2
- PDCD10 | c.96+1G>A p.X32_splice | Splice Site (SNP) | VAF 62/284 reads (22%) | catalogued as COSV101208551; called by muse, mutect2, varscan2
- PDE10A | c.874G>T p.V292L | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV100605349; called by muse, mutect2, varscan2
- PDLIM2 | c.316G>A p.G106S (on ENST00000397760; = p.G356S on NM_021630.6) | Missense Mutation (SNP) | VAF 100/248 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV56131625; called by muse, mutect2, varscan2
- PDZRN3 | c.2252A>G p.D751G | Missense Mutation (SNP) | VAF 28/40 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99730901; called by muse, mutect2, varscan2
- PGM1 | c.1433A>T p.D478V | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100936627; called by muse, mutect2, varscan2
- PHIP | c.3181G>T p.A1061S | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.978); catalogued as COSV99244565; called by muse, mutect2, varscan2
- PKHD1 | c.3744G>A p.W1248* | Nonsense Mutation (SNP) | VAF 51/116 reads (44%) | catalogued as COSV100583821; called by muse, mutect2, varscan2
- PKHD1L1 | c.7295T>A p.I2432K | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as COSV101006583; called by muse, mutect2, varscan2
- PLCL2 | c.2836G>A p.E946K (on ENST00000615277 / NM_001144382.2; = p.E820K on NM_015184.5) | Missense Mutation (SNP) | VAF 190/239 reads (79%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV101196881; called by muse, mutect2, varscan2
- PLEKHO2 | c.592G>C p.E198Q | Missense Mutation (SNP) | VAF 64/229 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.154); catalogued as COSV100060844; called by muse, mutect2, varscan2
- PLG | c.2161C>A p.L721I | Missense Mutation (SNP) | VAF 51/118 reads (43%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.473); catalogued as COSV100369399, COSV57518606; called by muse, mutect2, varscan2
- PLPPR5 | c.694T>G p.C232G | Missense Mutation (SNP) | VAF 73/160 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.09); catalogued as COSV99587613; called by muse, mutect2, varscan2
- PLXNA4 | c.4274T>A p.L1425Q | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100325711; called by muse, mutect2, varscan2
- PLXNA4 | c.1613G>T p.R538L | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.983); catalogued as COSV100325715; called by muse, mutect2, varscan2
- POF1B | c.118C>A p.Q40K | Missense Mutation (SNP) | VAF 38/43 reads (88%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.117); catalogued as COSV99427045; called by muse, mutect2, varscan2
- POLR2G | c.424G>T p.E142* | Nonsense Mutation (SNP) | VAF 74/186 reads (40%) | catalogued as COSV100080144; called by muse, mutect2, varscan2
- POM121L12 | c.518G>T p.C173F | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as COSV101374947; called by muse, mutect2, varscan2
- PPP1R9A | c.2167G>T p.E723* | Nonsense Mutation (SNP) | VAF 18/51 reads (35%) | catalogued as COSV99196496; called by muse, mutect2, varscan2
- PRDM9 | c.1762G>C p.G588R | Missense Mutation (SNP) | VAF 52/244 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.42); catalogued as COSV99690768; called by muse, mutect2, varscan2
- PRG2 | c.130C>A p.Q44K | Missense Mutation (SNP) | VAF 76/166 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.045); catalogued as COSV100314979; called by muse, mutect2, varscan2
- PTPRB | c.5551G>A p.E1851K | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV54233283, COSV99718179; called by muse, mutect2, varscan2
- PTPRN2 | c.530A>G p.Q177R | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT tolerated (0.48); PolyPhen benign (0.01); catalogued as COSV101234962; called by muse, mutect2, varscan2
- RAB3GAP1 | c.665C>T p.P222L | Missense Mutation (SNP) | VAF 97/250 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.476); catalogued as CD133239, COSV99921446; called by muse, mutect2, varscan2
- RAC1 | c.348A>C p.K116N | Missense Mutation (SNP) | VAF 80/161 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.915); catalogued as COSV100641041; called by muse, mutect2, varscan2
- RAD23B | c.890C>T p.S297F | Missense Mutation (SNP) | VAF 83/199 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100787746; called by muse, mutect2, varscan2
- RECQL4 | c.1939C>A p.R647S | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs775127620, COSV99467960; called by muse, varscan2
- REG1A | c.140G>T p.C47F | Missense Mutation (SNP) | VAF 139/344 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.467); catalogued as COSV99286869; called by muse, mutect2, varscan2
- RGS6 | c.545G>A p.R182Q | Missense Mutation (SNP) | VAF 137/197 reads (70%) | SIFT deleterious (0); PolyPhen benign (0.137); catalogued as rs745879240, COSV59566797, COSV59588304; called by muse, mutect2, varscan2
- RHPN2 | c.1589T>A p.L530* | Nonsense Mutation (SNP) | VAF 48/142 reads (34%) | catalogued as COSV99577961; called by muse, mutect2, varscan2
- RIN1 | c.428A>T p.Q143L | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as COSV100254818; called by muse, mutect2, varscan2
- RNF44 | c.1236G>T p.K412N | Missense Mutation (SNP) | VAF 44/62 reads (71%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV99221949; called by muse, mutect2, varscan2
- ROBO2 | c.3407G>A p.G1136D | Missense Mutation (SNP) | VAF 88/111 reads (79%) | SIFT deleterious (0); PolyPhen possibly damaging (0.527); catalogued as COSV100168360; called by muse, mutect2, varscan2
- ROCK1 | c.3525C>G p.H1175Q | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101296501; called by muse, mutect2, varscan2
- RP1 | c.4252G>T p.D1418Y | Missense Mutation (SNP) | VAF 50/144 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.173); catalogued as COSV99608220; called by muse, mutect2, varscan2
- RPS6KA6 | c.1000G>A p.D334N | Missense Mutation (SNP) | VAF 32/34 reads (94%) | SIFT tolerated (0.29); PolyPhen benign (0.02); catalogued as COSV99425102; called by muse, mutect2, varscan2
- RUNDC3B | c.418G>A p.A140T | Missense Mutation (SNP) | VAF 81/239 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55946795; called by muse, mutect2, varscan2
- RUNX1T1 | c.1455G>T p.K485N (on ENST00000265814 / NM_001198628.1; = p.K458N on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/117 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs1226273355, COSV56146466; called by muse, mutect2, varscan2
- RXFP2 | c.425T>A p.L142Q | Missense Mutation (SNP) | VAF 39/51 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100034446; called by muse, mutect2, varscan2
- RYR1 | c.425G>A p.G142E | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1568435830, COSV100616342; called by muse, mutect2, varscan2
- RYR2 | c.3055G>T p.G1019C | Missense Mutation (SNP) | VAF 42/55 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100771940; called by muse, mutect2, varscan2
- RYR2 | c.5695C>T p.P1899S | Missense Mutation (SNP) | VAF 66/76 reads (87%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV63674487; called by muse, mutect2, varscan2
- SAMD3 | c.1454C>A p.S485Y | Missense Mutation (SNP) | VAF 66/177 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100696295; called by muse, mutect2, varscan2
- SCRIB | c.3846+1G>T p.X1282_splice | Splice Site (SNP) | VAF 21/61 reads (34%) | catalogued as COSV100253751; called by muse, mutect2, varscan2
- SELP | c.1027G>C p.A343P | Missense Mutation (SNP) | VAF 152/179 reads (85%) | SIFT tolerated (0.27); PolyPhen benign (0.026); catalogued as COSV99740570; called by muse, mutect2, varscan2
- SEMA5A | c.2705G>A p.W902* | Nonsense Mutation (SNP) | VAF 16/65 reads (25%) | catalogued as COSV101228536; called by muse, mutect2, varscan2
- SGIP1 | c.1448G>T p.R483I | Missense Mutation (SNP) | VAF 98/284 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99392197; called by muse, mutect2, varscan2
- SHANK2 | c.3334G>T p.V1112L | Missense Mutation (SNP) | VAF 43/1034 reads (4%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.91); catalogued as COSV99575141; called by muse, mutect2
- SIAH3 | c.349G>T p.E117* | Nonsense Mutation (SNP) | VAF 70/98 reads (71%) | catalogued as COSV101247945, COSV68553407; called by muse, mutect2, varscan2
- SLC11A2 | c.1136C>G p.S379W (on ENST00000394904 / NM_001379455.1; = p.S350W on NM_000617.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 63/168 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV100014917; called by muse, mutect2, varscan2
- SLC24A4 | c.1851G>A p.M617I | Missense Mutation (SNP) | VAF 29/32 reads (91%) | SIFT tolerated (0.08); PolyPhen benign (0.028); catalogued as rs982263808, COSV100105640; called by muse, mutect2, varscan2
- SLIT2 | c.2022G>T p.W674C | Missense Mutation (SNP) | VAF 55/66 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99885579; called by muse, mutect2, varscan2
- SLIT2 | c.2641C>T p.P881S | Missense Mutation (SNP) | VAF 109/123 reads (89%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV99885583; called by muse, mutect2, varscan2
- SLITRK2 | c.2005T>A p.Y669N | Missense Mutation (SNP) | VAF 87/102 reads (85%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV100157984; called by muse, mutect2, varscan2
- SLITRK4 | c.1238T>C p.I413T | Missense Mutation (SNP) | VAF 134/160 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100567429; called by muse, mutect2, varscan2
- SLITRK5 | c.2072G>T p.R691L | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100280985, COSV61524615; called by muse, mutect2, varscan2
- SNX14 | c.2080G>A p.D694N (on ENST00000314673 / NM_001350535.1; = p.D641N on NM_020468.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.267); catalogued as COSV100121675; called by muse, mutect2, varscan2
- SORCS1 | c.2190C>A p.C730* | Nonsense Mutation (SNP) | VAF 23/27 reads (85%) | catalogued as COSV99542907, COSV99548202; called by muse, mutect2, varscan2
- SPATA31E1 | c.3154A>C p.S1052R | Missense Mutation (SNP) | VAF 68/201 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.367); catalogued as COSV100350747; called by muse, mutect2, varscan2
- SPATA31E1 | c.3811C>A p.P1271T | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.231); catalogued as rs757134749, COSV100350748; called by muse, mutect2, varscan2
- SPATA5 | c.1669C>T p.H557Y | Missense Mutation (SNP) | VAF 88/118 reads (75%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs766447688, COSV56783427; called by muse, mutect2, varscan2
- SSTR4 | c.612C>A p.H204Q | Missense Mutation (SNP) | VAF 46/187 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as COSV99658676; called by muse, mutect2, varscan2
- STAB2 | c.1755A>T p.E585D | Missense Mutation (SNP) | VAF 165/408 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101186147; called by muse, mutect2, varscan2
- SYCP2L | c.443T>C p.I148T | Missense Mutation (SNP) | VAF 99/131 reads (76%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); catalogued as COSV99305516; called by muse, mutect2, varscan2
- TANC2 | c.3573G>A p.M1191I | Missense Mutation (SNP) | VAF 44/86 reads (51%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as COSV101267604; called by muse, mutect2, varscan2
- TAS1R1 | c.1028G>A p.R343Q | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.7); PolyPhen benign (0.011); catalogued as rs1374921534, COSV100039762; called by mutect2, varscan2
- TBR1 | c.184C>G p.Q62E | Missense Mutation (SNP) | VAF 69/161 reads (43%) | SIFT tolerated (1); PolyPhen possibly damaging (0.9); catalogued as COSV101271501, COSV101271553; called by muse, mutect2, varscan2
- TEP1 | c.5575G>C p.V1859L | Missense Mutation (SNP) | VAF 60/88 reads (68%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV99402843; called by muse, mutect2, varscan2
- TGM2 | c.756G>T p.M252I | Missense Mutation (SNP) | VAF 87/160 reads (54%) | SIFT tolerated (0.07); PolyPhen benign (0.107); catalogued as COSV100821691; called by muse, mutect2, varscan2
- THEMIS | c.1759C>A p.R587S | Missense Mutation (SNP) | VAF 79/166 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64074150; called by muse, mutect2, varscan2
- TLN1 | c.2183G>T p.S728I | Missense Mutation (SNP) | VAF 75/103 reads (73%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.462); catalogued as COSV100147987; called by muse, mutect2, varscan2
- TLR4 | c.2133C>A p.D711E (on ENST00000355622 / NM_138554.5; = p.D671E on NM_003266.4) | Missense Mutation (SNP) | VAF 71/167 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100842815; called by muse, mutect2, varscan2
- TMEM132D | c.2539A>C p.M847L | Missense Mutation (SNP) | VAF 68/168 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV101242980, COSV67158871; called by muse, mutect2
- TMEM150A | c.5C>A p.T2N | Missense Mutation (SNP) | VAF 178/454 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.652); catalogued as COSV100108298; called by muse, mutect2, varscan2
- TMEM181 | c.1472G>T p.G491V | Missense Mutation (SNP) | VAF 87/222 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100892598; called by muse, mutect2, varscan2
- TMEM200A | c.548G>T p.G183V | Missense Mutation (SNP) | VAF 51/114 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.648); catalogued as rs931103745, COSV99759613; called by muse, mutect2, varscan2
- TMPRSS13 | c.622G>A p.A208T | Missense Mutation (SNP) | VAF 227/313 reads (73%) | SIFT tolerated (0.38); PolyPhen benign (0.114); catalogued as rs1324300487, COSV101471474, COSV101471512; called by muse, mutect2, varscan2
- TNC | c.5839C>A p.P1947T | Missense Mutation (SNP) | VAF 83/219 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV100406035; called by muse, mutect2, varscan2
- TNFSF14 | c.667C>T p.R223C | Missense Mutation (SNP) | VAF 116/277 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs772753769, COSV55590283; called by muse, mutect2, varscan2
- TRIM27 | c.902A>T p.D301V | Missense Mutation (SNP) | VAF 26/37 reads (70%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV101019397; called by muse, mutect2, varscan2
- TRIM47 | c.1453G>T p.E485* | Nonsense Mutation (SNP) | VAF 55/125 reads (44%) | catalogued as COSV99638586; called by muse, mutect2, varscan2
- TRPM8 | c.2941T>G p.Y981D | Missense Mutation (SNP) | VAF 51/135 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100224318; called by muse, mutect2, varscan2
- TTC8 | c.1329C>A p.N443K (on ENST00000338104 / NM_001288781.1; = p.N427K on NM_144596.4) | Missense Mutation (SNP) | VAF 67/87 reads (77%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); catalogued as COSV100581524; called by muse, mutect2, varscan2
- TTN | c.78667C>T p.P26223S (on ENST00000591111; = p.P18799S on NM_003319.4) | Missense Mutation (SNP) | VAF 53/134 reads (40%) | PolyPhen probably damaging (0.999); catalogued as rs1553568366, COSV100621166; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.48766T>C p.Y16256H (on ENST00000591111; = p.Y8832H on NM_003319.4) | Missense Mutation (SNP) | VAF 80/218 reads (37%) | PolyPhen probably damaging (0.998); catalogued as COSV100621168; called by muse, mutect2, varscan2
- TUBB6 | c.515C>T p.S172L | Missense Mutation (SNP) | VAF 112/227 reads (49%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (1); catalogued as COSV99302054; called by muse, mutect2, varscan2
- UGT2B4 | c.1034A>T p.D345V | Missense Mutation (SNP) | VAF 112/159 reads (70%) | SIFT deleterious (0.02); PolyPhen benign (0.269); catalogued as COSV100522539; called by muse, mutect2, varscan2
- UGT2B7 | c.1568C>A p.A523E | Missense Mutation (SNP) | VAF 52/79 reads (66%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1349721571, COSV100535251, COSV59445021; called by muse, mutect2, varscan2
- UNC13C | c.2449C>A p.Q817K | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as COSV52906351, COSV99511824; called by muse, varscan2
- UNC5D | c.1682-1G>A p.X561_splice | Splice Site (SNP) | VAF 42/88 reads (48%) | catalogued as COSV99777206; called by muse, mutect2, varscan2
- USP13 | c.1799-1G>T p.X600_splice | Splice Site (SNP) | VAF 94/411 reads (23%) | catalogued as COSV99830776, COSV99831456; called by muse, mutect2, varscan2
- USP30 | c.1265C>T p.P422L | Missense Mutation (SNP) | VAF 290/730 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs201279666; called by muse, mutect2, varscan2
- VPS13C | c.625-1G>T p.X209_splice (on ENST00000644861 / NM_020821.3; = p.X166_splice on NM_017684.5) | Splice Site (SNP) | VAF 41/90 reads (46%) | catalogued as COSV99829372; called by muse, mutect2, varscan2
- VPS8 | c.3049G>T p.V1017L (on ENST00000625842 / NM_001349294.1; = p.V1015L on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV99803002; called by muse, mutect2, varscan2
- WDR45 | c.514G>C p.V172L (on ENST00000376372 / NM_001029896.2; = p.V173L on NM_007075.3) | Missense Mutation (SNP) | VAF 35/38 reads (92%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as COSV100540330; called by muse, mutect2, varscan2
- WDR91 | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 94/255 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.328); catalogued as COSV100615775, COSV60371854; called by muse, mutect2, varscan2
- WIZ | c.184G>T p.D62Y | Missense Mutation (SNP) | VAF 104/259 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99653519; called by muse, mutect2, varscan2
- WNK3 | c.517G>T p.V173F | Missense Mutation (SNP) | VAF 92/117 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100671714; called by muse, mutect2, varscan2
- ZEB2 | c.3241T>C p.C1081R | Missense Mutation (SNP) | VAF 64/156 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100356477; called by muse, mutect2, varscan2
- ZFAT | c.2363A>G p.H788R | Missense Mutation (SNP) | VAF 97/257 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100914785; called by muse, mutect2, varscan2
- ZFHX4 | c.2259C>A p.C753* | Nonsense Mutation (SNP) | VAF 23/46 reads (50%) | catalogued as COSV51507602, COSV99265249; called by muse, mutect2, varscan2
- ZFP42 | c.68G>T p.S23I | Missense Mutation (SNP) | VAF 52/69 reads (75%) | SIFT tolerated (0.21); PolyPhen benign (0.102); catalogued as COSV100479010; called by muse, mutect2, varscan2
- ZFR | c.138C>A p.S46R | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV99416251; called by muse, mutect2
- ZIC1 | c.165G>C p.E55D | Missense Mutation (SNP) | VAF 96/151 reads (64%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51557280; called by muse, mutect2, varscan2
- ZMYM1 | c.1475G>A p.R492K | Missense Mutation (SNP) | VAF 60/174 reads (34%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV63251507; called by muse, mutect2, varscan2
- ZNF117 | c.290A>C p.N97T | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.367); catalogued as COSV99275899; called by muse, mutect2, varscan2
- ZNF253 | c.399C>G p.N133K | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.386); catalogued as COSV100849555; called by muse, mutect2, varscan2
- ZNF292 | c.538G>C p.V180L | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100370751; called by muse, mutect2, varscan2
- ZNF320 | c.1202C>T p.A401V | Missense Mutation (SNP) | VAF 63/178 reads (35%) | SIFT tolerated (0.55); PolyPhen benign (0.056); catalogued as rs748325945, COSV101206896; called by muse, mutect2, varscan2
- ZNF407 | c.1264G>T p.V422L | Missense Mutation (SNP) | VAF 53/121 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs772796599, COSV55252402, COSV99996218; called by muse, mutect2, varscan2
- ZNF442 | c.1195C>T p.H399Y | Missense Mutation (SNP) | VAF 175/432 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99664449; called by muse, mutect2, varscan2
- ZNF548 | c.904G>T p.V302F | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.133); catalogued as COSV100278229; called by muse, mutect2, varscan2
- ZNF578 | c.208A>T p.M70L | Missense Mutation (SNP) | VAF 114/355 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV101405089; called by muse, mutect2, varscan2
- ZNF578 | c.209T>G p.M70R | Missense Mutation (SNP) | VAF 118/361 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.143); catalogued as COSV101405090; called by muse, mutect2, varscan2
- ZNF582 | c.1061T>C p.L354P | Missense Mutation (SNP) | VAF 113/259 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100018817; called by muse, mutect2, varscan2
- ZNF761 | c.1372A>G p.R458G | Missense Mutation (SNP) | VAF 81/189 reads (43%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.97); catalogued as COSV100483437; called by muse, mutect2, varscan2
- ZNF782 | c.1691G>C p.C564S | Missense Mutation (SNP) | VAF 165/436 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100001497; called by muse, mutect2, varscan2
- ZNF835 | c.961C>A p.L321M | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101606379; called by muse, varscan2
- ZNF835 | c.785C>A p.S262Y | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.924); catalogued as rs1422731054, COSV101606380; called by muse, mutect2, varscan2
- ZNF835 | c.314G>T p.G105V | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0.13); catalogued as COSV101606381; called by muse, mutect2, varscan2
- ZSCAN1 | c.179G>C p.W60S | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.896); catalogued as COSV56606635, COSV99991843; called by muse, mutect2, varscan2
- ANO10 | c.1836del p.I613Yfs*10 | Frame Shift Del (DEL) | VAF 47/82 reads (57%) | called by mutect2, pindel, varscan2
- CDKN2A | c.466del p.D156Ifs*37 | Frame Shift Del (DEL) | VAF 27/37 reads (73%) | called by mutect2, varscan2
- CDKN2A | c.465del p.D156Ifs*37 | Frame Shift Del (DEL) | VAF 29/64 reads (45%) | called by mutect2*, pindel, varscan2*
- CYLD | c.538del p.V180Cfs*23 | Frame Shift Del (DEL) | VAF 107/198 reads (54%) | called by mutect2, pindel, varscan2
- HOXD4 | c.311del p.P104Rfs*34 | Frame Shift Del (DEL) | VAF 12/35 reads (34%) | called by mutect2, pindel, varscan2
- IGLV1-50 | c.145G>T p.G49W | Missense Mutation (SNP) | VAF 452/511 reads (88%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- ITPR3 | c.6857dup p.A2287Cfs*26 | Frame Shift Ins (INS) | VAF 38/116 reads (33%) | called by mutect2, pindel, varscan2
- JPH1 | c.183_188del p.Q61_Y63delinsH | In Frame Del (DEL) | VAF 12/44 reads (27%) | called by pindel, varscan2
- MEIOC | c.1056dup p.L353Ifs*7 | Frame Shift Ins (INS) | VAF 13/36 reads (36%) | called by mutect2, pindel, varscan2
- PDZK1 | c.1291G>C p.V431L | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); called by mutect2, varscan2
- PIGN | c.500del p.G167Vfs*33 | Frame Shift Del (DEL) | VAF 67/278 reads (24%) | called by mutect2, pindel, varscan2
- RAI1 | c.2687del p.P896Hfs*54 | Frame Shift Del (DEL) | VAF 28/74 reads (38%) | called by mutect2, pindel, varscan2
- RNF17 | c.704dup p.N235Kfs*2 | Frame Shift Ins (INS) | VAF 43/74 reads (58%) | called by mutect2, varscan2
- RPS6KA3 | c.889_890del p.L298Ffs*21 | Frame Shift Del (DEL) | VAF 78/138 reads (57%) | called by pindel, varscan2
- SLITRK4 | c.968dup p.N323Kfs*49 | Frame Shift Ins (INS) | VAF 126/192 reads (66%) | called by mutect2, pindel, varscan2
- SPDYE5 | c.763G>C p.A255P | Missense Mutation (SNP) | VAF 111/252 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF605 | c.202A>T p.R68* | Nonsense Mutation (SNP) | VAF 31/96 reads (32%) | called by muse, mutect2, varscan2
- ZNF658 | c.719A>G p.E240G | Missense Mutation (SNP) | VAF 79/175 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZSWIM2 | c.336dup p.I113Dfs*13 | Frame Shift Ins (INS) | VAF 129/377 reads (34%) | called by mutect2, pindel, varscan2
- A2M | c.618G>A p.V206= | Silent (SNP) | VAF 136/337 reads (40%) | catalogued as COSV59385796; called by muse, mutect2, varscan2
- AP5B1 | c.1593G>C p.P531= | Silent (SNP) | VAF 15/31 reads (48%) | catalogued as rs758507175, COSV100376106, COSV57503423; called by muse, mutect2, varscan2
- APOL3 | c.327C>T p.F109= (on ENST00000349314 / NM_145640.2; = p.F38= on NM_014349.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 54/164 reads (33%) | catalogued as rs61731691, COSV62579496; called by muse, mutect2, varscan2
- ARHGAP30 | c.2127T>C p.S709= | Silent (SNP) | VAF 282/654 reads (43%) | catalogued as COSV100920379; called by muse, mutect2, varscan2
- ATM | c.8304A>G p.E2768= | Silent (SNP) | VAF 181/243 reads (74%) | catalogued as rs756686570, COSV99590643; called by muse, mutect2, varscan2
- ATP6V0A2 | c.957G>T p.V319= | Silent (SNP) | VAF 52/124 reads (42%) | catalogued as COSV100377087; called by muse, mutect2, varscan2
- BRINP1 | c.1410G>A p.R470= | Silent (SNP) | VAF 31/102 reads (30%) | catalogued as COSV99776242; called by muse, mutect2, varscan2
- C10orf71 | c.2067G>A p.Q689= | Silent (SNP) | VAF 27/38 reads (71%) | catalogued as COSV60504549, COSV60513920; called by muse, mutect2, varscan2
- C7orf26 | c.1056G>T p.L352= | Silent (SNP) | VAF 19/59 reads (32%) | catalogued as COSV100732958; called by muse, mutect2, varscan2
- CACNA2D2 | c.642C>T p.I214= | Silent (SNP) | VAF 235/305 reads (77%) | catalogued as COSV99818031; called by muse, mutect2, varscan2
- CALN1 | c.174G>A p.K58= (on ENST00000329008 / NM_001017440.3; = p.K100= on NM_031468.4) | Silent (SNP) | VAF 29/67 reads (43%) | catalogued as rs763607879, COSV100208174; called by muse, mutect2, varscan2
- CCDC185 | c.1212C>G p.A404= | Silent (SNP) | VAF 53/60 reads (88%) | catalogued as COSV100838816; called by muse, mutect2, varscan2
- CCDC85A | c.1479T>A p.A493= | Silent (SNP) | VAF 56/119 reads (47%) | catalogued as COSV101339496; called by muse, mutect2, varscan2
- CCNJL | c.1092C>T p.H364= | Silent (SNP) | VAF 54/73 reads (74%) | catalogued as COSV99979652; called by muse, mutect2, varscan2
- CDCA3 | c.756A>G p.Q252= | Silent (SNP) | VAF 54/111 reads (49%) | catalogued as COSV99977019; called by muse, mutect2, varscan2
- CENPT | c.1554G>A p.L518= | Silent (SNP) | VAF 133/175 reads (76%) | catalogued as COSV99535250; called by muse, mutect2, varscan2
- CNBD1 | c.1077G>T p.V359= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs772452419, COSV101582275; called by muse, varscan2
- CNTN1 | c.2919T>A p.V973= | Silent (SNP) | VAF 161/343 reads (47%) | catalogued as COSV100751657; called by muse, mutect2, varscan2
- COG2 | c.1977G>A p.K659= | Silent (SNP) | VAF 63/70 reads (90%) | catalogued as rs199784400, COSV100794729; called by muse, mutect2, varscan2
- COL11A1 | c.133C>T p.L45= | Silent (SNP) | VAF 53/144 reads (37%) | catalogued as COSV100617496; called by muse, varscan2
- COL14A1 | c.2160A>T p.P720= | Silent (SNP) | VAF 74/186 reads (40%) | catalogued as COSV99919996; called by muse, mutect2, varscan2
- CPN2 | c.69C>A p.P23= | Silent (SNP) | VAF 264/366 reads (72%) | catalogued as COSV100102855; called by muse, mutect2, varscan2
- CSF2RA | c.276C>T p.V92= | Silent (SNP) | VAF 169/460 reads (37%) | catalogued as rs1370426161, COSV100817846; called by muse, mutect2, varscan2
- DDO | c.834G>A p.R278= (on ENST00000368924 / NM_001368172.1; = p.R219= on NM_004032.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 143/381 reads (38%) | catalogued as COSV100927881; called by muse, mutect2, varscan2
- DDX28 | c.711G>T p.L237= | Silent (SNP) | VAF 31/39 reads (79%) | catalogued as COSV100193053; called by muse, mutect2, varscan2
- DENND4A | c.2250A>C p.A750= | Silent (SNP) | VAF 6/10 reads (60%) | catalogued as COSV101475387; called by muse, varscan2
- DIS3L2 | c.2103G>A p.S701= | Silent (SNP) | VAF 64/187 reads (34%) | catalogued as rs766200831, COSV99806825; called by muse, mutect2, varscan2
- DMRTC2 | c.441C>A p.P147= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV54186890, COSV99523437; called by muse, mutect2, varscan2
- DNAH8 | c.6444C>T p.C2148= | Silent (SNP) | VAF 72/186 reads (39%) | catalogued as rs777410917, COSV59443914; called by muse, mutect2, varscan2
- EDA2R | c.261G>A p.L87= | Silent (SNP) | VAF 11/13 reads (85%) | catalogued as rs1216447298, COSV53632277, COSV99490816; called by muse, mutect2, varscan2
- EPHA3 | c.2799G>T p.T933= | Silent (SNP) | VAF 78/109 reads (72%) | catalogued as COSV100346865, COSV60705893; called by muse, mutect2
- EPHA6 | c.1071C>T p.C357= | Silent (SNP) | VAF 58/275 reads (21%) | catalogued as COSV101064353; called by muse, mutect2, varscan2
- ESRRG | c.144C>T p.S48= | Silent (SNP) | VAF 96/121 reads (79%) | catalogued as COSV100753320; called by muse, mutect2, varscan2
- FAT2 | c.6090G>A p.R2030= | Silent (SNP) | VAF 99/130 reads (76%) | catalogued as rs894204935, COSV99943589; called by muse, mutect2, varscan2
- FRG2B | c.450G>A p.R150= | Silent (SNP) | VAF 38/261 reads (15%) | catalogued as COSV101423530; called by muse, mutect2
- FRMPD3 | c.2766G>A p.K922= | Silent (SNP) | VAF 7/10 reads (70%) | catalogued as COSV99346716; called by muse, mutect2, varscan2
- GABRA2 | c.1347C>T p.V449= | Silent (SNP) | VAF 75/98 reads (77%) | catalogued as COSV100734572, COSV62919132; called by muse, mutect2, varscan2
- GGTLC1 | c.465G>A p.V155= | Silent (SNP) | VAF 181/333 reads (54%) | catalogued as COSV99600801; called by muse, mutect2, varscan2
- GPA33 | c.738T>A p.V246= | Silent (SNP) | VAF 96/113 reads (85%) | catalogued as COSV100901160, COSV63301137; called by muse, mutect2, varscan2
- GPR149 | c.960C>A p.V320= | Silent (SNP) | VAF 243/571 reads (43%) | catalogued as COSV101078574; called by muse, mutect2, varscan2
- GPR22 | c.858T>A p.T286= | Silent (SNP) | VAF 53/105 reads (50%) | catalogued as COSV99772643; called by muse, mutect2, varscan2
- GRIA2 | c.1896C>T p.I632= | Silent (SNP) | VAF 175/239 reads (73%) | catalogued as COSV99645268; called by muse, mutect2, varscan2
- GRM5 | c.19C>T p.L7= | Silent (SNP) | VAF 27/45 reads (60%) | catalogued as COSV59594733; called by muse, mutect2, varscan2
- GUCY1A1 | c.1011G>T p.G337= | Silent (SNP) | VAF 83/117 reads (71%) | catalogued as rs201711745, COSV99638165; called by muse, mutect2, varscan2
- HDX | c.1416G>C p.V472= | Silent (SNP) | VAF 30/38 reads (79%) | catalogued as rs753746449, COSV99947672; called by muse, mutect2, varscan2
- HECTD3 | c.1602A>T p.A534= | Silent (SNP) | VAF 41/100 reads (41%) | catalogued as COSV100938170; called by muse, mutect2, varscan2
- HMGCLL1 | c.186T>G p.A62= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as COSV99232735; called by muse, mutect2, varscan2
- HS3ST4 | c.1011G>T p.A337= | Silent (SNP) | VAF 148/196 reads (76%) | catalogued as COSV100499813, COSV100502128; called by muse, mutect2, varscan2
- HYDIN | c.6216G>T p.L2072= | Silent (SNP) | VAF 58/103 reads (56%) | catalogued as COSV99993284; called by muse, mutect2, varscan2
- IGKV1D-43 | c.120A>G p.R40= | Silent (SNP) | VAF 112/285 reads (39%) | called by muse, mutect2, varscan2
- IL1RAPL2 | c.420G>A p.L140= | Silent (SNP) | VAF 162/204 reads (79%) | catalogued as COSV100781640; called by muse, mutect2, varscan2
- ILF3 | c.1842T>C p.F614= | Silent (SNP) | VAF 83/206 reads (40%) | catalogued as COSV51558408, COSV99139974; called by muse, mutect2, varscan2
- ITFG2 | c.618G>A p.A206= | Silent (SNP) | VAF 44/111 reads (40%) | catalogued as rs373908169, COSV57389115; called by muse, mutect2, varscan2
- KCNK17 | c.429C>G p.L143= | Silent (SNP) | VAF 103/296 reads (35%) | catalogued as COSV100950251; called by muse, mutect2, varscan2
- KIAA1522 | c.2559G>A p.L853= (on ENST00000373480 / NM_001198972.2; = p.L912= on NM_020888.3) | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as COSV99614886; called by muse, mutect2, varscan2
- LAMA1 | c.2892G>T p.T964= | Silent (SNP) | VAF 31/57 reads (54%) | catalogued as COSV101057018; called by muse, mutect2, varscan2
- LAMA4 | c.4380C>T p.S1460= (on ENST00000230538 / NM_001105206.3; = p.S1453= on NM_002290.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 89/219 reads (41%) | catalogued as COSV100038896; called by muse, mutect2, varscan2
- LAMB2 | c.3822G>A p.E1274= | Silent (SNP) | VAF 81/108 reads (75%) | catalogued as COSV100026347; called by muse, mutect2, varscan2
- LIPG | c.1080C>T p.N360= | Silent (SNP) | VAF 43/134 reads (32%) | catalogued as COSV99724587; called by muse, mutect2, varscan2
- LRP2 | c.7263C>T p.V2421= | Silent (SNP) | VAF 73/176 reads (41%) | catalogued as COSV99789483; called by muse, mutect2, varscan2
- LRP3 | c.957C>T p.D319= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as rs745317448, COSV99472395; called by muse, varscan2
- LRRC4C | c.1602G>T p.V534= | Silent (SNP) | VAF 66/83 reads (80%) | catalogued as rs376625739, COSV99540373; called by muse, mutect2, varscan2
- LRRN1 | c.78C>A p.S26= | Silent (SNP) | VAF 65/87 reads (75%) | catalogued as COSV100076477; called by muse, mutect2, varscan2
- MAGEB4 | c.420C>T p.S140= | Silent (SNP) | VAF 28/32 reads (88%) | catalogued as COSV100975050; called by muse, mutect2, varscan2
- MEOX1 | c.387C>T p.G129= | Silent (SNP) | VAF 155/382 reads (41%) | catalogued as rs753290944, COSV100233762; called by muse, mutect2, varscan2
- MGAM | c.5331G>A p.T1777= | Silent (SNP) | VAF 13/25 reads (52%) | catalogued as rs374695000, COSV101527600; called by muse, mutect2, varscan2
- MRC2 | c.2121G>T p.L707= | Silent (SNP) | VAF 25/59 reads (42%) | catalogued as COSV100316479; called by muse, mutect2, varscan2
- MUC16 | c.39465C>A p.P13155= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as rs369281815, COSV101109665, COSV101109988; called by muse, mutect2, varscan2
- MUC17 | c.11001C>A p.I3667= | Silent (SNP) | VAF 90/242 reads (37%) | catalogued as rs761868422, COSV100074269, COSV100074446; called by muse, mutect2, varscan2
- MUC3A | c.7671T>C p.I2557= | Silent (SNP) | VAF 191/686 reads (28%) | catalogued as COSV100115016; called by muse, mutect2, varscan2
- MYH1 | c.2409G>T p.V803= | Silent (SNP) | VAF 48/171 reads (28%) | catalogued as COSV99876440; called by muse, mutect2, varscan2
- MYH15 | c.2826G>A p.E942= | Silent (SNP) | VAF 88/359 reads (25%) | catalogued as rs1454837716, COSV99843836; called by muse, mutect2, varscan2
- MYMK | c.444C>T p.S148= | Silent (SNP) | VAF 52/128 reads (41%) | catalogued as rs538117168, COSV60599989, COSV60600171; called by muse, mutect2, varscan2
- NEXMIF | c.3231T>C p.P1077= | Silent (SNP) | VAF 117/157 reads (75%) | catalogued as COSV99281304; called by muse, mutect2, varscan2
- NFKB2 | c.2271C>A p.P757= | Silent (SNP) | VAF 38/59 reads (64%) | catalogued as COSV99193022; called by muse, mutect2, varscan2
- NLGN4X | c.259C>A p.R87= | Silent (SNP) | VAF 78/95 reads (82%) | catalogued as CM095218, COSV52018302, COSV99322910; called by muse, mutect2, varscan2
- NLRP12 | c.474C>A p.T158= | Silent (SNP) | VAF 107/247 reads (43%) | catalogued as COSV100145524; called by muse, mutect2, varscan2
- NPAP1 | c.1326T>G p.P442= | Silent (SNP) | VAF 56/170 reads (33%) | catalogued as COSV100275711; called by muse, mutect2, varscan2
- NPHS1 | c.516C>T p.T172= | Silent (SNP) | VAF 23/58 reads (40%) | catalogued as CD087053, COSV100800100; called by muse, mutect2, varscan2
- OGA | c.1464T>G p.V488= | Silent (SNP) | VAF 215/301 reads (71%) | catalogued as COSV100761912; called by muse, mutect2, varscan2
- OPN3 | c.795G>A p.L265= | Silent (SNP) | VAF 108/131 reads (82%) | catalogued as COSV100087604; called by muse, mutect2, varscan2
- OR10K2 | c.798C>T p.Y266= | Silent (SNP) | VAF 137/157 reads (87%) | catalogued as rs780531944, COSV100149569, COSV59221546; called by muse, mutect2, varscan2
- OR11G2 | c.615C>A p.S205= | Silent (SNP) | VAF 59/79 reads (75%) | catalogued as COSV100639926; called by muse, mutect2, varscan2
- OR52B6 | c.756C>A p.A252= | Silent (SNP) | VAF 159/212 reads (75%) | catalogued as COSV100798514; called by muse, mutect2, varscan2
- OR5A2 | c.852C>A p.P284= | Silent (SNP) | VAF 54/126 reads (43%) | catalogued as COSV100119798, COSV100119827; called by muse, mutect2, varscan2
- OR5AN1 | c.285T>C p.F95= | Silent (SNP) | VAF 164/401 reads (41%) | catalogued as COSV100004404; called by muse, mutect2, varscan2
- OR5J2 | c.511C>T p.L171= | Silent (SNP) | VAF 76/198 reads (38%) | catalogued as COSV100399150, COSV56620719; called by muse, mutect2, varscan2
- OR5M8 | c.435G>T p.T145= | Silent (SNP) | VAF 48/139 reads (35%) | catalogued as COSV59118435; called by muse, mutect2, varscan2
- PARP1 | c.2988G>A p.Q996= | Silent (SNP) | VAF 54/62 reads (87%) | catalogued as rs1418377811, COSV100828990; called by muse, mutect2, varscan2
- PDZD2 | c.495C>T p.C165= | Silent (SNP) | VAF 59/246 reads (24%) | catalogued as COSV99225852; called by muse, mutect2, varscan2
- PHF21A | c.1212C>T p.V404= (on ENST00000418153 / NM_001101802.3; = p.V405= on NM_016621.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 116/733 reads (16%) | catalogued as COSV99138890; called by muse, mutect2, varscan2
- PIK3C2G | c.2754T>G p.P918= (on ENST00000676171; = p.P877= on NM_004570.5) | Silent (SNP) | VAF 65/160 reads (41%) | catalogued as COSV99852778; called by muse, mutect2, varscan2
- PIP5K1C | c.168G>A p.K56= | Silent (SNP) | VAF 101/236 reads (43%) | catalogued as rs1181934403, COSV100095751; called by muse, mutect2, varscan2
- PKHD1L1 | c.2319C>T p.S773= | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as COSV101006581; called by muse, mutect2, varscan2
- PLSCR5 | c.534C>A p.I178= | Silent (SNP) | VAF 63/91 reads (69%) | catalogued as rs756037414, COSV101494504; called by muse, mutect2, varscan2
- POLR3B | c.123A>G p.K41= | Silent (SNP) | VAF 50/99 reads (51%) | catalogued as COSV99943670; called by muse, mutect2, varscan2
- PON2 | c.972G>A p.G324= | Silent (SNP) | VAF 59/156 reads (38%) | catalogued as COSV56002160; called by muse, mutect2, varscan2
- PPP1R3A | c.1215A>G p.S405= | Silent (SNP) | VAF 201/419 reads (48%) | catalogued as COSV99493502; called by muse, mutect2, varscan2
- RBP3 | c.2481C>A p.P827= | Silent (SNP) | VAF 15/24 reads (63%) | called by muse, mutect2, varscan2
- RELN | c.3882C>A p.T1294= | Silent (SNP) | VAF 92/268 reads (34%) | catalogued as COSV100634259; called by muse, mutect2, varscan2
- RGL3 | c.1515A>G p.P505= | Silent (SNP) | VAF 59/154 reads (38%) | catalogued as rs1483009711, COSV100993049; called by muse, mutect2, varscan2
- RORB | c.645A>G p.A215= (on ENST00000396204 / NM_001365023.1; = p.A204= on NM_006914.4) | Silent (SNP) | VAF 52/132 reads (39%) | catalogued as COSV100974400; called by muse, mutect2, varscan2
- RPS4Y2 | c.384G>A p.K128= | Silent (SNP) | VAF 53/64 reads (83%) | catalogued as COSV99978416; called by muse, mutect2, varscan2
- SHF | c.1143G>C p.V381= | Silent (SNP) | VAF 21/69 reads (30%) | catalogued as COSV99334629; called by muse, mutect2, varscan2
- SLC15A3 | c.256C>T p.L86= | Silent (SNP) | VAF 4/9 reads (44%) | catalogued as rs756228627, COSV99928887; called by muse, varscan2
- SLC20A2 | c.1041G>T p.V347= | Silent (SNP) | VAF 98/222 reads (44%) | catalogued as COSV100646146; called by muse, mutect2, varscan2
- SLC24A5 | c.708C>A p.A236= | Silent (SNP) | VAF 29/67 reads (43%) | catalogued as COSV99981902; called by muse, mutect2, varscan2
- SLC5A8 | c.126C>T p.S42= | Silent (SNP) | VAF 28/70 reads (40%) | catalogued as COSV101610575; called by muse, mutect2, varscan2
- TCF7L2 | c.894C>T p.V298= (on ENST00000355995 / NM_001367943.1; = p.V275= on NM_030756.5) | Silent (SNP) | VAF 62/84 reads (74%) | catalogued as COSV99526320; called by muse, mutect2, varscan2
- TEX2 | c.372A>G p.A124= | Silent (SNP) | VAF 117/241 reads (49%) | catalogued as COSV99367263; called by muse, mutect2, varscan2
- TPTE2 | c.573T>A p.L191= (on ENST00000400230 / NM_199254.2; = p.L114= on NM_130785.3) | Silent (SNP) | VAF 29/40 reads (73%) | catalogued as COSV99690651; called by muse, mutect2, varscan2
- TRPM7 | c.696G>T p.L232= | Silent (SNP) | VAF 58/116 reads (50%) | catalogued as rs1263446706, COSV100540080; called by muse, mutect2, varscan2
- TTN | c.23727C>A p.T7909= (on ENST00000591111; = p.T6982= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 49/111 reads (44%) | catalogued as COSV100621170; called by muse, mutect2, varscan2
- TXLNB | c.1038G>A p.A346= | Silent (SNP) | VAF 69/160 reads (43%) | catalogued as rs763243962, COSV100625087; called by muse, mutect2, varscan2
- UNC13C | c.2485T>C p.L829= | Silent (SNP) | VAF 42/81 reads (52%) | catalogued as COSV99520553; called by muse, varscan2
- VPS13B | c.10785G>A p.L3595= | Silent (SNP) | VAF 51/113 reads (45%) | catalogued as COSV100662695, COSV62160171; called by muse, mutect2, varscan2
- WDFY1 | c.465G>A p.T155= | Silent (SNP) | VAF 53/135 reads (39%) | catalogued as rs1234653600, COSV99239677; called by muse, mutect2, varscan2
- WEE2 | c.1329C>A p.I443= | Silent (SNP) | VAF 52/128 reads (41%) | catalogued as rs1328530785, COSV101187673; called by muse, mutect2, varscan2
- YTHDF1 | c.1326G>T p.G442= | Silent (SNP) | VAF 85/125 reads (68%) | catalogued as rs1419542415, COSV100945594; called by muse, mutect2, varscan2
- ZBTB22 | c.936G>T p.L312= | Silent (SNP) | VAF 56/168 reads (33%) | catalogued as COSV99802395; called by muse, mutect2
- ZNF493 | c.1434T>C p.C478= | Silent (SNP) | VAF 25/65 reads (38%) | catalogued as rs537126271, COSV100828790; called by muse, mutect2, varscan2
- ZNF566 | c.39A>G p.V13= | Silent (SNP) | VAF 90/235 reads (38%) | catalogued as COSV101091498; called by muse, mutect2, varscan2
- ANKS1B | c.2420-50C>A | Intron (SNP) | VAF 48/97 reads (49%) | catalogued as COSV60360284; called by muse, mutect2, varscan2
- C3P1 | n.3426G>A | RNA (SNP) | VAF 91/184 reads (49%) | called by muse, mutect2, varscan2
- COL5A3 | c.*1G>T | 3'UTR (SNP) | VAF 46/107 reads (43%) | catalogued as COSV99319337; called by muse, mutect2, varscan2
- CTTN | c.*469G>C | 3'UTR (SNP) | VAF 10/305 reads (3%) | catalogued as COSV100098042; called by muse, mutect2
- FMO3 | c.133-2011C>A | Intron (SNP) | VAF 27/33 reads (82%) | catalogued as COSV100882506; called by muse, mutect2, varscan2
- GATA3 | chr10:8050996 G>T | 5'Flank (SNP) | VAF 12/15 reads (80%) | called by muse, mutect2, varscan2
- MIR1270 | chr19:20397811 C>A | 3'Flank (SNP) | VAF 58/157 reads (37%) | called by muse, mutect2, varscan2
- MIR30D | n.19G>T | RNA (SNP) | VAF 87/211 reads (41%) | catalogued as rs1441595222; called by muse, mutect2, varscan2
- MIR520B | n.60G>T | RNA (SNP) | VAF 35/78 reads (45%) | called by muse, mutect2, varscan2
- MIR521-1 | n.66T>A | RNA (SNP) | VAF 55/142 reads (39%) | called by muse, mutect2, varscan2
- OGFOD3 | c.824-1959C>A | Intron (SNP) | VAF 83/148 reads (56%) | catalogued as COSV100234464; called by muse, mutect2, varscan2
- OSBPL1A | c.626-2897G>T | Intron (SNP) | VAF 12/34 reads (35%) | catalogued as COSV100112236; called by muse, mutect2, varscan2
- TCF7 | c.1149-24G>T | Intron (SNP) | VAF 102/138 reads (74%) | catalogued as rs1308533480, COSV100390045, COSV100390113; called by muse, mutect2, varscan2
